Somatic mutation profile of tumor specimen TCGA-KL-8343-01A (aliquot TCGA-KL-8343-01A-11D-2310-10) from TCGA case TCGA-KL-8343, project TCGA-KICH (Kidney Chromophobe). Sex at birth: male; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 72.7 years (26,562 days).
Specimen TCGA-KL-8343-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b60fec3a-ae59-413e-93a0-070005074361.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KL-8343-11A (Solid Tissue Normal), aliquot TCGA-KL-8343-11A-01D-2310-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c3202617-3cc2-4396-b3dc-3afabfd2082d

The open-access MAF lists 34 somatic variants for this specimen: 23 protein-altering or splice-affecting, 7 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 7, Frame Shift Del 3, RNA 2, Splice Site 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMPD2 | c.354-2A>T p.X118_splice | Splice Site (SNP) | VAF 42/85 reads (49%) | catalogued as rs1448759721, COSV99858114; called by muse, mutect2, varscan2
- CARMIL2 | c.18C>G p.D6E | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as COSV100576313; called by muse, mutect2
- CTSD | c.1205A>G p.N402S | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.194); catalogued as COSV99362563; called by muse, mutect2, varscan2
- HROB | c.257C>A p.T86K | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV55368847; called by muse, mutect2, varscan2
- LAMA1 | c.6186G>T p.M2062I | Missense Mutation (SNP) | VAF 68/195 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as rs1253836785, COSV101057297; called by muse, mutect2, varscan2
- MAGEB2 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 51/63 reads (81%) | SIFT tolerated (0.09); PolyPhen benign (0.139); catalogued as COSV66781132; called by muse, mutect2, varscan2
- NLRP6 | c.2077C>T p.R693W | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as COSV100380918; called by muse, mutect2, varscan2
- PAX4 | c.80G>A p.R27Q | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770477634, COSV58391722; called by muse, mutect2, varscan2
- ROBO2 | c.2756C>T p.P919L | Missense Mutation (SNP) | VAF 96/246 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV59901461; called by muse, mutect2, varscan2
- TKTL2 | c.390A>T p.L130F | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99761752; called by muse, mutect2
- TRIM54 | c.525C>A p.S175R (on ENST00000380075 / NM_187841.3; = p.S217R on NM_032546.4) | Missense Mutation (SNP) | VAF 74/192 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as COSV99274184; called by muse, varscan2
- ADCY4 | c.1994C>G p.A665G | Missense Mutation (SNP) | VAF 55/163 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- CHRDL2 | c.1147_1150del p.K383Sfs*28 (on ENST00000376332 / NM_001304415.1; = p.E401Vfs*47 on NM_015424.6 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 22/71 reads (31%) | called by mutect2, pindel, varscan2
- DMD | c.10023_10033del p.F3341Lfs*7 | Frame Shift Del (DEL) | VAF 76/126 reads (60%) | called by mutect2, pindel, varscan2
- DROSHA | c.858G>T p.E286D | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ETNK1 | c.731C>T p.S244F | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.315); called by muse, mutect2
- HSPD1 | c.800A>T p.H267L | Missense Mutation (SNP) | VAF 91/219 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- IL18RAP | c.1634T>A p.V545D | Missense Mutation (SNP) | VAF 21/201 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.39); called by muse, mutect2, varscan2
- INO80 | c.3218C>G p.A1073G | Missense Mutation (SNP) | VAF 42/140 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.009); called by muse, varscan2
- NYAP2 | c.215T>A p.I72K | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RCN1 | c.351del p.F117Lfs*33 | Frame Shift Del (DEL) | VAF 37/101 reads (37%) | called by mutect2, pindel, varscan2
- RNF111 | c.1780G>T p.V594F | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- SEZ6L | c.2141C>A p.T714N | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.133); called by muse, varscan2
- CHIT1 | c.783C>A p.I261= | Silent (SNP) | VAF 31/46 reads (67%) | catalogued as rs1246065511; called by muse, mutect2, varscan2
- CHST3 | c.1149C>T p.R383= | Silent (SNP) | VAF 16/30 reads (53%) | catalogued as rs1169930642, COSV64150306; called by muse, varscan2
- CUL7 | c.414T>C p.L138= | Silent (SNP) | VAF 19/126 reads (15%) | called by muse, mutect2, varscan2
- LRRC43 | c.645C>T p.Y215= | Silent (SNP) | VAF 31/71 reads (44%) | catalogued as rs758326623, COSV100336875; called by muse, mutect2, varscan2
- MYCBP2 | c.2676T>C p.P892= (on ENST00000357337; = p.P930= on NM_015057.5) | Silent (SNP) | VAF 60/228 reads (26%) | catalogued as rs1355488221; called by muse, mutect2, varscan2
- TIGD5 | c.351G>T p.R117= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as COSV100364184; called by muse, mutect2, varscan2
- UGT8 | c.510T>G p.A170= | Silent (SNP) | VAF 142/338 reads (42%) | called by muse, mutect2, varscan2
- LINC01276 | n.549G>A | RNA (SNP) | VAF 9/248 reads (4%) | catalogued as rs1228130309; called by muse, mutect2
- RPS4Y2 | c.-26G>T | 5'UTR (SNP) | VAF 129/177 reads (73%) | called by muse, mutect2, varscan2
- SLC25A14 | c.*6G>T | 3'UTR (SNP) | VAF 7/66 reads (11%) | catalogued as COSV99502658; called by muse, mutect2
- SSPOP | n.4375G>T | RNA (SNP) | VAF 33/116 reads (28%) | catalogued as rs1462958298, COSV100023020; called by muse, mutect2, varscan2
